Somatic mutation profile of tumor specimen TCGA-BP-4988-01A (aliquot TCGA-BP-4988-01A-01D-1462-08) from TCGA case TCGA-BP-4988, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 72.8 years (26,576 days).
Specimen TCGA-BP-4988-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7446ce3-81d2-42a8-9d90-f09d90486364.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4988-11A (Solid Tissue Normal), aliquot TCGA-BP-4988-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2810f2d4-0446-44d9-9b66-6c762ab71fb3

The open-access MAF lists 52 somatic variants for this specimen: 39 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, 3'UTR 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.2921+1G>A p.X974_splice | Splice Site (SNP) | VAF 10/120 reads (8%) | catalogued as rs587781558, CS991304, COSV53740769, COSV53748775, COSV53767471; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- VHL | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 6/51 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913346, CM164440, CM941379, COSV56543253, COSV56550270, COSV56558440, COSV56563690; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.2684C>G p.S895C | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV52975737; called by muse, mutect2, varscan2
- AHNAK2 | c.4632G>T p.Q1544H | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as rs1566914687, COSV60914236; called by muse, mutect2
- ANKS4B | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as rs373521474, COSV61140164; called by muse, varscan2
- APMAP | c.1209C>G p.F403L | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV54173685; called by muse, mutect2
- ATP13A4 | c.864G>T p.L288F | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55068843; called by muse, mutect2
- ATXN1 | c.1863C>G p.S621R | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV55214932; called by muse, mutect2
- BOD1L1 | c.3391G>A p.V1131M | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV50011097; called by muse, mutect2
- CNTN6 | c.901A>G p.N301D | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63160485; called by muse, mutect2, varscan2
- CRELD1 | c.1117A>G p.I373V | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99926763; called by muse, varscan2
- CTDP1 | c.2339A>T p.K780M | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50002771; called by muse, varscan2
- EIF5 | c.728T>A p.L243H | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV53685071; called by muse, mutect2
- GABRB1 | c.97A>C p.N33H | Missense Mutation (SNP) | VAF 31/438 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.383); catalogued as COSV54979376; called by muse, mutect2
- GCN1 | c.4547-2A>G p.X1516_splice | Splice Site (SNP) | VAF 7/53 reads (13%) | catalogued as COSV56107203; called by muse, mutect2, varscan2
- GLS2 | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57665461; called by muse, mutect2
- GPRC5D | c.974C>G p.P325R | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV57432669; called by muse, mutect2
- LCT | c.3026C>A p.A1009E | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.075); catalogued as COSV51548207; called by muse, mutect2, varscan2
- LRP2 | c.7966G>T p.E2656* | Nonsense Mutation (SNP) | VAF 19/146 reads (13%) | catalogued as COSV55550984, COSV55567174; called by muse, mutect2, varscan2
- MANEA | c.756C>G p.Y252* | Nonsense Mutation (SNP) | VAF 11/182 reads (6%) | catalogued as COSV62589588; called by muse, mutect2
- MFSD8 | c.1420del p.Q474Kfs*18 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | catalogued as CM120919; called by mutect2, pindel
- NUP214 | c.5555G>C p.G1852A | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63909168; called by muse, mutect2
- OBI1 | c.519A>C p.K173N | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV56145454; called by muse, mutect2, varscan2
- PBRM1 | c.2548C>T p.R850* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | catalogued as COSV56273176; called by muse, mutect2, varscan2
- PCDH10 | c.192A>C p.L64F | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52092716; called by muse, mutect2, varscan2
- RALGPS2 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV61336852; called by muse, mutect2
- RGS3 | c.2267C>T p.P756L (on ENST00000350696 / NM_001282923.2; = p.P475L on NM_130795.4) | Missense Mutation (SNP) | VAF 6/163 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV59515551; called by muse, mutect2
- SCCPDH | c.901A>T p.R301W | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV63618397; called by muse, mutect2, varscan2
- SLK | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.423); catalogued as COSV100212146; called by muse, mutect2
- SPATA31D1 | c.2419A>T p.T807S | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV61195162, COSV61200743; called by muse, mutect2, varscan2
- TKTL2 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54918533; called by muse, mutect2
- TRIM6 | c.391T>G p.F131V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV53475825; called by muse, mutect2, varscan2
- UBTD2 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV67143228; called by muse, mutect2
- USP34 | c.2444A>G p.H815R | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs1345998096, COSV68400717; called by muse, mutect2
- XYLT2 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV50017637; called by muse, mutect2, varscan2
- ZNF136 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs1036144497, COSV59710729, COSV59711667; called by muse, mutect2
- ZNF44 | c.1819C>T p.P607S (on ENST00000356109 / NM_001164276.2; = p.P559S on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV61135231; called by muse, mutect2, varscan2
- DNTTIP2 | c.195_200del p.R67_K68del | In Frame Del (DEL) | VAF 10/107 reads (9%) | called by mutect2, pindel
- ST8SIA4 | c.930del p.A311Rfs*10 | Frame Shift Del (DEL) | VAF 17/124 reads (14%) | called by mutect2, pindel, varscan2
- ALG9 | c.774C>A p.A258= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as rs1555140959, COSV67644267; called by muse, mutect2
- CHRD | c.1776G>T p.T592= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV52607413; called by muse, mutect2, varscan2
- CSNK1G3 | c.489A>G p.V163= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as COSV62054353; called by muse, mutect2
- ITGB4 | c.1518G>A p.E506= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV52325152; called by muse, varscan2
- NSD1 | c.2418A>C p.I806= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV61775494; called by muse, mutect2, varscan2
- SLC24A1 | c.3000C>T p.D1000= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV56051503; called by muse, mutect2
- SPIDR | c.703T>C p.L235= | Silent (SNP) | VAF 31/276 reads (11%) | catalogued as COSV52375796; called by muse, varscan2
- THSD4 | c.2193C>T p.C731= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV55968743, COSV55978727; called by muse, mutect2
- TRAPPC9 | c.993T>C p.I331= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs762256611, COSV66898371; called by mutect2, varscan2
- VHL | c.474G>C p.L158= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as CX071477, COSV56548860; called by muse, mutect2, varscan2
- ZMYM3 | c.150T>C p.P50= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58737606; called by muse, mutect2
- NFIA | c.*53T>C | 3'UTR (SNP) | VAF 8/119 reads (7%) | catalogued as COSV100783400; called by muse, mutect2
- PKD1L2 | n.850G>C | RNA (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
